Somatic mutation profile of tumor specimen MMRF_2699_1_BM_CD138pos (aliquot MMRF_2699_1_BM_CD138pos_T1_KHS5U_L14428) from MMRF case MMRF_2699, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.3 years (23,485 days).
Specimen MMRF_2699_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74c45127-c8f8-49ed-8110-6599d10ddc2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2699_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2699_1_PB_WBC_C2_KHS5U_L14429; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c69d1765-35af-4986-8ca8-da5d18ba61a8

The open-access MAF lists 139 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 34, Silent 19, Intron 15, 5'UTR 7, 5'Flank 6, RNA 3, Frame Shift Ins 2, 3'Flank 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1M1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52227468; called by muse, mutect2, varscan2
- B4GALT6 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs901456078, COSV52704419; called by muse, mutect2, varscan2
- CDCA5 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99298068; called by muse, mutect2, varscan2
- CRAMP1 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs747446342; called by muse, mutect2, varscan2
- CSMD1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as rs1038449254, COSV101217504; called by muse, mutect2, varscan2
- DAND5 | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100397231; called by muse, mutect2, varscan2
- DDX42 | c.1648C>G p.P550A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV63789410; called by muse, mutect2
- DDX51 | c.495dup p.F166Vfs*19 | Frame Shift Ins (INS) | VAF 21/56 reads (38%) | catalogued as rs749572607; called by mutect2, varscan2
- DOCK7 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762552417; called by muse, mutect2, varscan2
- DSCAML1 | c.472G>A p.D158N (on ENST00000321322; = p.D98N on NM_020693.4) | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs1276241297, COSV58396974; called by muse, mutect2, varscan2
- ELP3 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1389420251; called by muse, mutect2, varscan2
- IGFBP6 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56857154; called by muse, mutect2, varscan2
- IGLV3-1 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as rs753612185; called by muse, varscan2
- MAP1A | c.7882C>T p.R2628C | Missense Mutation (SNP) | VAF 154/322 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776917730; called by muse, mutect2, varscan2
- MAP3K15 | c.3616C>T p.R1206W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.855); catalogued as rs774477994, COSV58834415; called by muse, mutect2, varscan2
- NETO2 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57451212, COSV57451626; called by muse, mutect2, varscan2
- NEURL1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1180968072; called by muse, mutect2, varscan2
- PCSK5 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.318); catalogued as rs775597557; called by muse, mutect2, varscan2
- RRBP1 | c.3951+1G>A p.X1317_splice (on ENST00000377813 / NM_001365613.2; = p.X884_splice on NM_004587.3) | Splice Site (SNP) | VAF 16/117 reads (14%) | catalogued as rs1221015124; called by muse, mutect2, varscan2
- TP63 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 179/631 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs751300168, COSV53195986; called by muse, mutect2, varscan2
- USP19 | c.2524T>A p.F842I | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60044901; called by muse, mutect2, varscan2
- ZFHX4 | c.9654dup p.E3219Rfs*17 | Frame Shift Ins (INS) | VAF 85/367 reads (23%) | catalogued as rs1219274378, COSV99256254; called by mutect2, pindel, varscan2
- ZNFX1 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65575243; called by muse, mutect2, varscan2
- AKAP8 | c.1384G>C p.D462H | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AKAP8 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, varscan2
- ALDH9A1 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ARHGEF28 | c.4669G>C p.E1557Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- ARID4B | c.2240A>G p.D747G | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DPY19L3 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HNRNPF | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- IGHJ6 | c.14_28del p.Y5_V9del | In Frame Del (DEL) | VAF 35/71 reads (49%) | called by pindel, varscan2
- IPO5 | c.446A>C p.E149A | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KRBOX1 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC7 | c.643C>A p.P215T (on ENST00000651989 / NM_001370785.2; = p.P182T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MSH5 | c.778A>G p.R260G | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MUC16 | c.18484T>A p.S6162T | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCKAP5 | c.33C>A p.D11E | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- NFKBIA | c.161_179del p.L54Rfs*30 | Frame Shift Del (DEL) | VAF 62/220 reads (28%) | called by mutect2, pindel, varscan2
- OVCH1 | c.1524G>A p.M508I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PLEKHN1 | c.811G>T p.G271C (on ENST00000379409; = p.G219C on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PSMB5 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMC5 | c.895G>C p.D299H | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM18 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SEMA6D | c.2422T>G p.F808V (on ENST00000316364 / NM_153618.2; = p.F746V on NM_020858.2) | Missense Mutation (SNP) | VAF 205/933 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SMARCD2 | c.1059C>G p.I353M | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOCS6 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2
- SP140 | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPAG4 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SYVN1 | c.863A>G p.D288G | Missense Mutation (SNP) | VAF 243/552 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TOX | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT tolerated (0.67); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- TRAF3IP3 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPC3 | c.762G>C p.M254I (on ENST00000379645 / NM_001366479.2; = p.M181I on NM_003305.2) | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XIRP1 | c.4453G>A p.A1485T | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARRB1 | c.1254A>G p.R418= | Silent (SNP) | VAF 32/201 reads (16%) | catalogued as rs75039319; called by muse, mutect2, varscan2
- CYP2D7 | c.1428C>G p.T476= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- ETS2 | c.114T>C p.A38= | Silent (SNP) | VAF 61/118 reads (52%) | called by muse, mutect2, varscan2
- LRRC49 | c.831T>C p.D277= | Silent (SNP) | VAF 127/602 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.14694G>A p.R4898= | Silent (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- MXRA5 | c.7329C>T p.N2443= | Silent (SNP) | VAF 50/178 reads (28%) | catalogued as rs41310268, COSV54249500; called by muse, mutect2, varscan2
- NLRP5 | c.3033G>A p.T1011= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs187988999; called by muse, mutect2, varscan2
- NMBR | c.60C>T p.S20= | Silent (SNP) | VAF 69/153 reads (45%) | catalogued as rs200079850, COSV57800421; called by muse, mutect2, varscan2
- PEG10 | c.594C>T p.N198= (on ENST00000482108 / NM_001040152.2; = p.N232= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/268 reads (41%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.2008C>T p.L670= (on ENST00000283426; = p.L1026= on NM_052909.5) | Silent (SNP) | VAF 59/144 reads (41%) | called by muse, mutect2, varscan2
- PSMB5 | c.399C>T p.I133= | Silent (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- PSMB5 | c.105C>T p.L35= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as rs749585868, COSV100557356; called by muse, mutect2, varscan2
- PTGFR | c.543G>A p.A181= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs775712841, COSV66114459; called by muse, mutect2, varscan2
- RELN | c.2790C>T p.F930= | Silent (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- RGS7BP | c.183C>T p.N61= | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- SETD2 | c.2121A>G p.L707= | Silent (SNP) | VAF 112/312 reads (36%) | called by muse, mutect2, varscan2
- SI | c.1050T>C p.Y350= | Silent (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- SLC25A23 | c.384C>T p.D128= | Silent (SNP) | VAF 86/342 reads (25%) | catalogued as rs368298555, COSV51190279; called by muse, mutect2, varscan2
- TANC1 | c.5166G>A p.P1722= | Silent (SNP) | VAF 58/136 reads (43%) | catalogued as rs746679276, COSV55083458; called by muse, mutect2, varscan2
- AC007342.3 | chr16:53371319 C>T | 5'Flank (SNP) | VAF 32/64 reads (50%) | called by mutect2, varscan2
- ACTB | c.-27-101G>A | Intron (SNP) | VAF 48/129 reads (37%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.-339G>A | 5'UTR (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- AJUBA | c.-22G>A | 5'UTR (SNP) | VAF 49/106 reads (46%) | catalogued as rs971658442, COSV99400943; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848836 A>C | 5'Flank (SNP) | VAF 130/319 reads (41%) | called by muse, mutect2, varscan2
- AMER1 | c.*604del | 3'UTR (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- ANP32B | c.-45C>T | 5'UTR (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- BAALC | chr8:103230163 C>A | 3'Flank (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- BTBD3 | chr20:11917847 G>A | 5'Flank (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.*3053C>A | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- CCDC28A-AS1 | n.545T>G | RNA (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2
- CCDC62 | c.*388G>C | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- CCNB1 | c.*86T>G | 3'UTR (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- CD79B | c.*302C>T | 3'UTR (SNP) | VAF 16/229 reads (7%) | called by muse, mutect2
- CD79B | c.*43C>T | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- CDC42EP2 | c.-246G>A | 5'UTR (SNP) | VAF 38/173 reads (22%) | catalogued as rs538498465; called by muse, mutect2, varscan2
- CNTN3 | c.*880T>A | 3'UTR (SNP) | VAF 12/37 reads (32%) | catalogued as rs1034728281; called by muse, mutect2, varscan2
- COL27A1 | c.*73G>A | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- COL9A1 | c.1396-21T>A | Intron (SNP) | VAF 61/218 reads (28%) | called by muse, mutect2, varscan2
- DAZL | c.3+738G>A | Intron (SNP) | VAF 40/130 reads (31%) | catalogued as rs756278256; called by muse, mutect2, varscan2
- DEFB110 | c.*107T>C | 3'UTR (SNP) | VAF 78/123 reads (63%) | called by muse, mutect2, varscan2
- DEPP1 | c.-25-99C>T | Intron (SNP) | VAF 52/127 reads (41%) | called by muse, mutect2, varscan2
- DMWD | c.*91G>A | 3'UTR (SNP) | VAF 54/202 reads (27%) | called by muse, mutect2, varscan2
- EVA1A | c.85+181C>T | Intron (SNP) | VAF 114/273 reads (42%) | called by muse, mutect2, varscan2
- FHIT | c.*462C>T | 3'UTR (SNP) | VAF 33/104 reads (32%) | catalogued as rs889518326; called by muse, mutect2, varscan2
- FSD2 | c.*3608C>T | 3'UTR (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- GABRG1 | c.*2532A>G | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- GLRX | chr5:95824322 C>G | 5'Flank (SNP) | VAF 27/84 reads (32%) | called by muse, mutect2, varscan2
- GPM6B | c.*127C>T | 3'UTR (SNP) | VAF 61/115 reads (53%) | called by muse, mutect2, varscan2
- GPRC5B | c.*1480C>T | 3'UTR (SNP) | VAF 50/105 reads (48%) | called by muse, mutect2, varscan2
- ISCU | c.114+99C>G | Intron (SNP) | VAF 17/54 reads (31%) | called by mutect2, varscan2
- KATNIP | c.1390-109T>G | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- KLHL38 | c.*57A>C | 3'UTR (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- LDHD | c.327+28G>A | Intron (SNP) | VAF 22/40 reads (55%) | catalogued as rs1051147468; called by muse, mutect2, varscan2
- LINC01591 | n.418G>A | RNA (SNP) | VAF 60/214 reads (28%) | catalogued as rs181295694; called by muse, mutect2, varscan2
- LMNB2 | c.*2132A>C | 3'UTR (SNP) | VAF 82/202 reads (41%) | called by muse, mutect2, varscan2
- LMNB2 | c.*1164G>A | 3'UTR (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+1455T>C | Intron (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- MBIP | c.250-9T>C | Intron (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- MMP16 | c.*7505T>C | 3'UTR (SNP) | VAF 44/122 reads (36%) | called by muse, mutect2, varscan2
- MR1 | c.*3043del | 3'UTR (DEL) | VAF 7/64 reads (11%) | catalogued as rs1161423376; called by pindel, varscan2
- NAA50 | c.*1727G>A | 3'UTR (SNP) | VAF 6/19 reads (32%) | catalogued as rs906888027; called by muse, mutect2
- NLRP6 | chr11:278421 C>T | 5'Flank (SNP) | VAF 47/200 reads (24%) | catalogued as rs1174820152; called by muse, mutect2, varscan2
- NUDT16 | c.*3128C>T | 3'UTR (SNP) | VAF 71/240 reads (30%) | called by muse, mutect2, varscan2
- OR2L1P | n.575C>G | RNA (SNP) | VAF 136/296 reads (46%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110170148 A>T | 3'Flank (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- PCDH15 | c.*3235A>G | 3'UTR (SNP) | VAF 23/59 reads (39%) | catalogued as COSV64716254; called by muse, mutect2, varscan2
- PDE7A | c.-457_-456insGCGGCGGCG | 5'UTR (INS) | VAF 3/37 reads (8%) | called by pindel, varscan2*
- PRAMEF14 | c.*311G>A | 3'UTR (SNP) | VAF 65/210 reads (31%) | called by muse, mutect2, varscan2
- PROS1 | c.*482G>A | 3'UTR (SNP) | VAF 94/187 reads (50%) | called by muse, mutect2, varscan2
- PSMB5 | chr14:23035152 G>C | 5'Flank (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- RBM24 | c.-52C>G | 5'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- RPLP0 | c.54+49A>C | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- SAMD3 | c.823-4595T>C | Intron (SNP) | VAF 19/54 reads (35%) | catalogued as rs1046955420; called by muse, mutect2, varscan2
- SLC25A20 | c.*191G>T | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- SLC25A48 | c.679+755C>T | Intron (SNP) | VAF 48/121 reads (40%) | called by muse, mutect2, varscan2
- SLC7A1 | c.*4476A>C | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.-496-79A>C | Intron (SNP) | VAF 39/134 reads (29%) | called by muse, mutect2, varscan2
- SLITRK4 | c.*397T>C | 3'UTR (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- SRPK2 | c.-154A>T | 5'UTR (SNP) | VAF 73/161 reads (45%) | called by muse, mutect2, varscan2
- SUGCT | c.*55A>G | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- TFR2 | c.473+42C>A | Intron (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- TMEM19 | c.*2311G>C | 3'UTR (SNP) | VAF 60/107 reads (56%) | called by muse, mutect2, varscan2
- TUB | c.*2288T>C | 3'UTR (SNP) | VAF 77/201 reads (38%) | called by muse, mutect2, varscan2
- UNC5B | c.*746A>G | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- WIPF2 | c.*150C>T | 3'UTR (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- ZDBF2 | c.*224_*226del | 3'UTR (DEL) | VAF 35/92 reads (38%) | catalogued as rs1401632886; called by pindel, varscan2
